RC case RC-B6E8 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2c052409-ee48-491c-85c3-ee2c90b6c2f6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1933; Vital status: Dead; Days to death: 261 days; Year of death: 2019; Cause of death: Cancer Related.

Diagnoses (4)
1. T-cell large granular lymphocytic leukemia (the primary disease): ICD-O-3 morphology code: 9831/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 85.5 years (31,219 days); Year of diagnosis: 2019; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Bone marrow / Peripheral blood.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 151 days; Days to treatment end: 195 days; Treatment outcome: Treatment Stopped Due to Toxicity; Reason treatment ended: Adverse Event; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Initial Diagnosis; Days to treatment start: 209 days; Days to treatment end: 258 days; Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Treatment Stopped Due to Toxicity; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Prior malignancy of the prostate gland (histology not recorded by GDC). Age at diagnosis: 74.9 years (27,350 days); Year of diagnosis: 2008; Days to diagnosis: -3,869 days (-10.6 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS.
3. Prior malignancy of the bladder (histology not recorded by GDC). Age at diagnosis: 80.5 years (29,388 days); Year of diagnosis: 2014; Days to diagnosis: -1,831 days (-5.0 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,763 days (-4.8 years); Treatment anatomic sites: Other.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Prior malignancy of the bladder (histology not recorded by GDC). Age at diagnosis: 80.5 years (29,388 days); Year of diagnosis: 2014; Days to diagnosis: -1,831 days (-5.0 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,819 days (-5.0 years); Treatment anatomic sites: Other.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (1 entry)
- Day 261 (end of treatment course 1): Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 94 kg; Height: 172 cm; BMI: 31.8.
- Timepoint category: Prior to Diagnosis; Comorbidities: Atrial Fibrillation / Hyperlipidemia / Peripheral Vascular Disease / Pulmonary Embolism / Cataracts / Hearing Loss / Osteoporosis or Osteopenia / Benign Prostatic Hyperplasia.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking onset year: 1953; Tobacco smoking quit year: 1983.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (2 samples)
- Sample RC-B6E8-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B6E8-TBP1-B: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
